Surgical pathology report (de-identified scan), TCGA case TCGA-HN-A2OB, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HN-A2OB-01A (Primary Tumor).

le Type Tumour Primary

hw 9/16/11

Sample Preparation Fresh Frozen
Site of Primary (Event) right breast
Site of Tissue Breast
Year of Sample Collection
Age at Sample Collection (yrs) 45
Sample Comments
Days to Procedure Date 0
Days to Diagnosis 14
Type of Procedure Surgical resection
Site of Primary (Histology) Right breast
Bilateral Disease
Tumour Size (cm) 2.7000000000000002
Histology Other
Grade/Differentiation Grade X - Unknown
Pathological T T2
Pathological N N1a
Number of Nodes Sampled 5
Number of Nodes Positive 2
Clinical M M0

ICD-0-3
carcinoma, infiltrating lobular, NOS
8520/3
Site: breast, NOS C50.9
hw
9/16/11

Histology Comments Histologic type: Invasive lobular (e cadherin negative). Modified Scarff
Bloom Richardson Grade: 1/3 (2). Total score 4/9.

SBR (Scarff-Bloom-Richardson) score 4
ER Status Positive NOS
PR Status Positive NOS
HER2 Status Negative
Lymph Node Metastases None Documented

Source: NCI Genomic Data Commons file 8b4efc40-8ea2-4ec7-8e0a-d00131bf9b14 (TCGA-HN-A2OB.32AE5A1A-703B-43C3-948A-719A90DDACC5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).